Somatic mutation profile of tumor specimen TCGA-IA-A83V-01A (aliquot TCGA-IA-A83V-01A-11D-A34Z-10) from TCGA case TCGA-IA-A83V, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.6 years (23,238 days).
Specimen TCGA-IA-A83V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d9077d86-67da-4642-a1e9-f760e416694a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IA-A83V-11A (Solid Tissue Normal), aliquot TCGA-IA-A83V-11A-11D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/21b46038-6d53-459d-9e9f-d184da48bdf2

The open-access MAF lists 65 somatic variants for this specimen: 49 protein-altering or splice-affecting, 15 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 15, Frame Shift Del 6, Splice Site 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGEF25 | c.1687C>G p.P563A | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV99677949; called by muse, mutect2, varscan2
- ASB2 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772682511, COSV60113444; called by muse, mutect2, varscan2
- BRCC3 | c.50A>G p.D17G | Missense Mutation (SNP) | VAF 24/41 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV100341608; called by muse, mutect2, varscan2
- BSN | c.7607C>T p.S2536L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99608437; called by muse, mutect2, varscan2
- CAPRIN1 | c.1888A>T p.N630Y | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100403876; called by muse, mutect2, varscan2
- CCNL1 | c.539A>G p.Q180R | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); catalogued as COSV99904195; called by muse, mutect2, varscan2
- CENPF | c.9043C>A p.L3015M | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100871690; called by muse, mutect2, varscan2
- CEP170 | c.2960A>C p.K987T | Missense Mutation (SNP) | VAF 66/418 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100317076; called by muse, mutect2, varscan2
- CLUL1 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.071); catalogued as rs1386208289, COSV100620977; called by muse, mutect2
- DNAJC17 | c.682-2A>T p.X228_splice | Splice Site (SNP) | VAF 19/77 reads (25%) | catalogued as COSV99591672; called by muse, mutect2, varscan2
- ECE1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99941826; called by muse, mutect2
- EDC4 | c.587A>T p.D196V | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99534416; called by muse, mutect2, varscan2
- FBXO11 | c.2168G>T p.R723I (on ENST00000403359 / NM_001190274.2; = p.R639I on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/258 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99315927; called by muse, mutect2, varscan2
- FER1L5 | c.3974T>C p.V1325A (on ENST00000623019; = p.V1298A on NM_001293083.2) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV101208871; called by muse, mutect2, varscan2
- FGD6 | c.383T>G p.V128G | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100676576; called by muse, mutect2, varscan2
- FMO1 | c.1547A>G p.K516R | Missense Mutation (SNP) | VAF 52/214 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as COSV100707771; called by muse, mutect2, varscan2
- FZD8 | c.1684G>C p.E562Q | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV101020227; called by muse, mutect2, varscan2
- GPR26 | c.233T>A p.L78Q | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV99500905; called by muse, mutect2
- HSPG2 | c.8255G>C p.G2752A | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV101020686; called by muse, mutect2, varscan2
- KANSL1 | c.2248C>T p.H750Y | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as COSV99294487; called by muse, mutect2, varscan2
- KCTD20 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99535975; called by muse, mutect2, varscan2
- LEO1 | c.1574G>T p.G525V | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100166510; called by muse, varscan2
- LONP2 | c.981T>C p.T327= | Splice Region (SNP) | VAF 44/145 reads (30%) | catalogued as COSV99589183; called by muse, mutect2, varscan2
- LUZP1 | c.2731G>C p.G911R | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV100034908; called by muse, mutect2, varscan2
- MIDN | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs1418165624, COSV99960226; called by muse, mutect2, varscan2
- MYH7 | c.3904A>G p.T1302A | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.524); catalogued as COSV100806104; called by muse, mutect2, varscan2
- OBSCN | c.18428A>G p.K6143R | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.788); catalogued as rs1326927404, COSV99477835; called by muse, mutect2, varscan2
- PIK3C2B | c.4636C>T p.L1546F | Missense Mutation (SNP) | VAF 47/204 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100916114; called by muse, mutect2, varscan2
- POMT1 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760216356, COSV100260997; called by muse, mutect2, varscan2
- PROSER3 | c.281T>C p.L94P | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99137442; called by mutect2, varscan2
- PSEN1 | c.1063C>G p.P355A | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs376433615, COSV99997824; called by muse, mutect2, varscan2
- RBP5 | c.355-1G>T p.X119_splice | Splice Site (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99870344, COSV99870528; called by muse, mutect2, varscan2
- RIPOR1 | c.3599G>A p.R1200Q (on ENST00000379312 / NM_001193522.2; = p.R1196Q on NM_024519.4) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99061988; called by muse, mutect2
- RRAS2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56329700, COSV56329705; called by muse, mutect2, varscan2
- SFMBT2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100739046; called by muse, mutect2, varscan2
- SPDYA | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.024); catalogued as COSV100066588; called by muse, mutect2, varscan2
- THRA | c.1397A>G p.E466G | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV99225498; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.205A>G p.K69E | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100925313; called by muse, mutect2, varscan2
- TNFAIP8L2 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs763092387, COSV100925314; called by muse, mutect2, varscan2
- TNPO2 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as COSV100790361; called by muse, mutect2
- VPS35L | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99220740; called by muse, mutect2, varscan2
- WDR24 | c.196A>G p.M66V (on ENST00000248142; = p.M4V on NM_032259.4) | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.239); catalogued as COSV99556608; called by muse, mutect2, varscan2
- AARS2 | c.766del p.L256Cfs*54 | Frame Shift Del (DEL) | VAF 11/52 reads (21%) | called by mutect2, varscan2
- NIPBL | c.5102_5103del p.S1701* | Frame Shift Del (DEL) | VAF 41/196 reads (21%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.1106del p.K369Rfs*41 (on ENST00000374531 / NM_001037293.2; = p.K401Rfs*41 on NM_053016.6) | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel
- RANBP6 | c.2561del p.L854Cfs*22 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by mutect2, varscan2
- SUPT20HL1 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 118/235 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TM7SF2 | c.941del p.F314Sfs*154 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- ZNF226 | c.2398_2401del p.K800Lfs*2 | Frame Shift Del (DEL) | VAF 11/73 reads (15%) | called by mutect2, pindel, varscan2
- ARHGAP10 | c.1920A>G p.S640= | Silent (SNP) | VAF 8/79 reads (10%) | catalogued as COSV100331231; called by muse, mutect2
- CBX1 | c.66G>A p.V22= | Silent (SNP) | VAF 19/301 reads (6%) | catalogued as COSV99848141; called by muse, mutect2
- DBR1 | c.435T>C p.S145= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99604512; called by muse, mutect2, varscan2
- ERAP1 | c.1485T>C p.D495= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV99700928; called by muse, mutect2, varscan2
- FA2H | c.195G>T p.P65= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV54725272, COSV99547758; called by muse, mutect2, varscan2
- FAF1 | c.288G>A p.R96= | Silent (SNP) | VAF 37/150 reads (25%) | catalogued as COSV100875563; called by muse, mutect2, varscan2
- IMP3 | c.528G>A p.E176= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV59189711; called by muse, mutect2, varscan2
- KRTAP5-11 | c.261C>T p.C87= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100651806; called by muse, mutect2, varscan2
- MEF2B | c.708C>T p.C236= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1364327725, COSV99364680; called by muse, mutect2, varscan2
- MRC2 | c.1635C>T p.A545= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100316246; called by muse, mutect2, varscan2
- MRPL38 | c.513C>A p.V171= | Silent (SNP) | VAF 31/68 reads (46%) | catalogued as rs754197091, COSV99485459; called by muse, mutect2, varscan2
- PRKDC | c.3090T>A p.G1030= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100040534; called by muse, mutect2, varscan2
- SEPTIN5 | c.996G>A p.L332= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV100820403; called by muse, mutect2, varscan2
- UBE2J1 | c.399T>A p.T133= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as COSV101470251; called by muse, mutect2, varscan2
- VCAN | c.3252T>A p.S1084= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs762103427, COSV54107405, COSV99425746; called by muse, mutect2, varscan2
- GATAD2A | c.-90-990T>A | Intron (SNP) | VAF 16/81 reads (20%) | catalogued as COSV99390156; called by muse, mutect2, varscan2
